Somatic mutation profile of tumor specimen TCGA-EL-A3H4-01A (aliquot TCGA-EL-A3H4-01A-11D-A202-08) from TCGA case TCGA-EL-A3H4, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 46.4 years (16,944 days).
Specimen TCGA-EL-A3H4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab00175e-1c7f-4f36-acdd-3d6ef9244e3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3H4-10A (Blood Derived Normal), aliquot TCGA-EL-A3H4-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da307017-0fea-4b4f-a69e-2d1f9f2fa50f

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCC2 | c.3568A>T p.I1190F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV64988803; called by muse, mutect2, varscan2
- CYLC2 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs188765977, COSV66336036; called by muse, mutect2, varscan2
- EMC4 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50785278; called by muse, mutect2, varscan2
- FAM135B | c.2431T>C p.S811P | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52756307; called by muse, mutect2
- MUC16 | c.18018C>A p.H6006Q | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV67497976; called by muse, mutect2, varscan2
- SLC6A8 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV53473639; called by muse, mutect2, varscan2
- ZBTB39 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55630813; called by muse, mutect2, varscan2
- DUOX2 | c.4247T>A p.F1416Y | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR1N2 | c.930T>C p.S310= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV65461320; called by muse, mutect2, varscan2
